Somatic mutation profile of tumor specimen 0DSZSH from CCDI case PBCITW, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Germinoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 17.7 years (6,472 days).
Specimen 0DSZSH: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8dccfe7c-8e5d-490f-859f-b39447b21beb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DSZSK (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/00641066-175a-4134-a135-d8c546cbce15

The open-access MAF lists 18 somatic variants for this specimen: 13 protein-altering or splice-affecting, 1 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 11, 3'UTR 4, Frame Shift Del 1, Translation Start Site 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KIT | c.1924A>G p.K642E | Missense Mutation (SNP) | VAF 172/769 reads (22%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913512, CM002803, COSV55387507, COSV55411978; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- NRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 278/1225 reads (23%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.339); catalogued as rs121913237, COSV54736383, COSV54736555, COSV54736974; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- RAC1 | c.53G>T p.C18F | Missense Mutation (SNP) | VAF 117/573 reads (20%) | hotspot (GDC flag); SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.454); catalogued as COSV100640958, COSV61822452, COSV61823434; called by muse, mutect2, varscan2
- KCTD7 | c.266C>T p.T89M | Missense Mutation (SNP) | VAF 352/1063 reads (33%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.576); catalogued as rs375586745; called by muse, mutect2, varscan2
- KIT | c.2446G>A p.D816N | Missense Mutation (SNP) | VAF 352/1322 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.863); catalogued as rs121913506, COSV55386862, COSV55387240, COSV55408330; called by muse, mutect2, varscan2
- NPHS1 | c.3554C>T p.P1185L | Missense Mutation (SNP) | VAF 72/384 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.031); catalogued as rs555255264, COSV100800437, COSV62287222; called by muse, mutect2, varscan2
- ZNF845 | c.1084A>G p.K362E | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.917); catalogued as rs1239350099, COSV72004794; called by muse, mutect2
- ERH | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 117/453 reads (26%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MORC2 | c.77A>G p.H26R | Missense Mutation (SNP) | VAF 281/728 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- PCDHA1 | c.26del p.L9Rfs*69 | Frame Shift Del (DEL) | VAF 44/326 reads (13%) | called by mutect2, varscan2
- RNF138 | c.496A>G p.N166D | Missense Mutation (SNP) | VAF 151/1251 reads (12%) | SIFT tolerated (0.05); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- RPS6KA6 | c.2144C>G p.T715S | Missense Mutation (SNP) | VAF 139/540 reads (26%) | SIFT tolerated (0.33); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLC26A5 | c.740C>A p.T247K | Missense Mutation (SNP) | VAF 76/770 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.216); called by muse, mutect2, varscan2
- ZNF845 | c.1083C>T p.D361= | Silent (SNP) | VAF 4/35 reads (11%) | catalogued as rs1180196074; called by muse, mutect2
- CHTOP | c.*91C>T | 3'UTR (SNP) | VAF 30/108 reads (28%) | called by muse, mutect2, varscan2
- OAS2 | c.*55C>T | 3'UTR (SNP) | VAF 44/363 reads (12%) | called by muse, mutect2, varscan2
- PIP4P2 | c.*24A>G | 3'UTR (SNP) | VAF 89/713 reads (12%) | called by muse, mutect2, varscan2
- RPAP2 | c.*89A>G | 3'UTR (SNP) | VAF 105/976 reads (11%) | called by muse, mutect2, varscan2
